Somatic mutation profile of tumor specimen TCGA-24-0982-01A (aliquot TCGA-24-0982-01A-01W-0488-09) from TCGA case TCGA-24-0982, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.2 years (28,201 days).
Specimen TCGA-24-0982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a800c6f2-65c8-40c5-97ce-e3e2c1eb878e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-0982-10C (Blood Derived Normal), aliquot TCGA-24-0982-10C-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d4ab803-0cf7-4f25-bd5b-63598834d87d

The open-access MAF lists 63 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 18, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 54/88 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV104387550; called by muse, mutect2
- BLVRA | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 22/385 reads (6%) | catalogued as rs754440828, COSV55516258; called by muse, mutect2
- BOD1L1 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50060830; called by muse, mutect2, varscan2
- CBLN4 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756451061, COSV50352834; called by muse, mutect2, varscan2
- CDH22 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 107/621 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs755330428, COSV64839607; called by muse, mutect2, varscan2
- CLDN15 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759019587, COSV57659722; called by muse, mutect2, varscan2
- CNOT1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV100409875; called by muse, mutect2, varscan2
- DLGAP5 | c.1141T>G p.C381G | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.223); catalogued as COSV55965236; called by muse, mutect2, varscan2
- DOCK1 | c.3601G>A p.V1201I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs952439430, COSV54744547; called by muse, mutect2, varscan2
- FAM83A | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs376602872; called by muse, mutect2, varscan2
- FBN2 | c.3021G>T p.W1007C | Missense Mutation (SNP) | VAF 70/568 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV52544043; called by muse, mutect2, varscan2
- FGB | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as CM141545, COSV57419491; called by muse, mutect2, varscan2
- FLG | c.5548G>A p.E1850K | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.262); catalogued as rs1377089283, COSV64237232; called by muse, mutect2
- GLCE | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55948308; called by muse, mutect2, varscan2
- HYAL3 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs189065354, COSV100269767; called by muse, mutect2, varscan2
- IARS1 | c.2385C>G p.D795E | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65117059; called by muse, mutect2, varscan2
- L3MBTL2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV99345722; called by muse, mutect2, varscan2
- PADI2 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV64946639; called by muse, mutect2, varscan2
- PCDHB5 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.068); catalogued as rs1554275802, COSV99169358; called by muse, mutect2
- PDE11A | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 23/245 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as COSV53707732; called by muse, mutect2
- PPP2R2B | c.1184T>G p.V395G (on ENST00000394409; = p.V461G on NM_181674.2) | Missense Mutation (SNP) | VAF 156/861 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs778098894, COSV60751353; called by muse, varscan2
- PSMB5 | c.32T>A p.L11Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV57801268; called by muse, mutect2, varscan2
- RGS21 | c.84C>A p.N28K | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs1461487573, COSV69883934; called by muse, mutect2, varscan2
- SCAMP5 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.506); catalogued as COSV62644176; called by muse, mutect2, varscan2
- SGPL1 | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 10/240 reads (4%) | catalogued as rs1196497635; called by muse, mutect2
- SIDT1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 95/624 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.129); catalogued as COSV53506725; called by muse, mutect2, varscan2
- SLC17A6 | c.1406A>G p.K469R | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs1308349633, COSV54141104; called by muse, mutect2, varscan2
- SLC35C2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 147/543 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV54758409; called by muse, mutect2, varscan2
- SMC1A | c.1744G>T p.D582Y | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV59131791; called by muse, mutect2, varscan2
- STXBP5L | c.1562A>G p.Y521C | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.701); catalogued as COSV56533814; called by muse, mutect2, varscan2
- SYBU | c.1979G>A p.R660H (on ENST00000276646 / NM_001099754.2; = p.R659H on NM_017786.6) | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs74885615; called by muse, mutect2, varscan2
- TP53I11 | c.528T>G p.I176M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV57534163; called by muse, mutect2, varscan2
- TUB | c.1364T>A p.F455Y (on ENST00000299506 / NM_177972.3; = p.F510Y on NM_003320.4) | Missense Mutation (SNP) | VAF 127/430 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55109960; called by muse, mutect2, varscan2
- ZKSCAN2 | c.418C>G p.R140G | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV60158645; called by muse, mutect2, varscan2
- ZNF16 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 208/1028 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV52765486; called by muse, mutect2, varscan2
- DENND4B | c.1971C>A p.H657Q | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- EPHX4 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- IL32 | c.32T>A p.M11K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by mutect2, varscan2
- INPP5B | c.982G>A p.V328M (on ENST00000373023; = p.V248M on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2
- ITGB4 | c.953del p.N318Tfs*58 | Frame Shift Del (DEL) | VAF 27/42 reads (64%) | called by mutect2, pindel, varscan2
- OR5V1 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 66/1102 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- POSTN | c.2466dup p.V823Sfs*5 | Frame Shift Ins (INS) | VAF 89/182 reads (49%) | called by mutect2, pindel, varscan2
- SLC6A6 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2
- ADAMTS12 | c.2349G>C p.L783= | Silent (SNP) | VAF 168/970 reads (17%) | catalogued as COSV61278572; called by muse, mutect2, varscan2
- CCDC40 | c.2517C>T p.D839= | Silent (SNP) | VAF 41/61 reads (67%) | catalogued as COSV66478609; called by muse, mutect2, varscan2
- COL16A1 | c.654C>G p.V218= | Silent (SNP) | VAF 54/84 reads (64%) | catalogued as COSV54713439; called by muse, mutect2, varscan2
- CREBBP | c.717G>C p.L239= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as rs1308030507; called by muse, mutect2
- DNAJB6 | c.570G>A p.S190= | Silent (SNP) | VAF 24/223 reads (11%) | catalogued as COSV51094840, COSV51100787; called by muse, mutect2, varscan2
- DNM1 | c.1773G>A p.T591= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs762812488, COSV57849538; called by muse, mutect2, varscan2
- H2BC7 | c.210C>T p.I70= | Silent (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- KCNA5 | c.558G>A p.R186= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs778119687, COSV52907929; called by muse, mutect2
- LRIG2 | c.2319G>A p.G773= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as COSV63164148; called by muse, mutect2, varscan2
- MBL2 | c.144C>A p.G48= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV64758688; called by muse, mutect2, varscan2
- MYO16 | c.153G>A p.A51= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as rs749546658, COSV51805323; called by muse, mutect2, varscan2
- MYOM2 | c.3150T>C p.I1050= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV50768437; called by muse, mutect2, varscan2
- NCAPD2 | c.3177G>A p.L1059= | Silent (SNP) | VAF 15/592 reads (3%) | called by muse, mutect2
- NPLOC4 | c.735G>A p.G245= | Silent (SNP) | VAF 12/92 reads (13%) | called by muse, varscan2
- SMC1B | c.735G>A p.V245= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- SPAG16 | c.819T>C p.G273= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV55989629; called by muse, mutect2, varscan2
- TM4SF19 | c.63C>T p.S21= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs1284968635, COSV99879434; called by muse, mutect2, varscan2
- TNS2 | c.753C>A p.I251= (on ENST00000314250 / NM_170754.4; = p.I261= on NM_015319.2) | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV58579028; called by muse, mutect2
- WNT4 | c.313+2325C>T | Intron (SNP) | VAF 18/28 reads (64%) | catalogued as rs761137242, COSV51605443; called by muse, mutect2, varscan2
